Somatic mutation profile of tumor specimen ASCProject_0059_T1_WES (aliquot ASCProject_0059_T1_WES_1) from CMI case ASCProject_0059, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.9 years (19,309 days).
Specimen ASCProject_0059_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 148df02f-fae5-420c-8e45-749e6914c216.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0059_SALIVA (Saliva), aliquot ASCProject_0059_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80efe21c-6e95-469e-bc37-c45922a39a3b

The open-access MAF lists 73 somatic variants for this specimen: 42 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 22, Intron 5, RNA 3, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CATSPERD | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV58464284; called by muse, mutect2, varscan2
- CD1A | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs761626527; called by muse, mutect2, varscan2
- CYP4F8 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57855688; called by muse, mutect2, varscan2
- DCHS1 | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs753521014, COSV54999815; called by muse, mutect2, varscan2
- GOLGA8F | c.682G>A p.D228N (on ENST00000526619; = p.D434N on NM_001350920.2) | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs772661040; called by muse, mutect2, varscan2
- HAPLN1 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as rs1434710716, COSV57151631; called by muse, mutect2, varscan2
- KRT72 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV53373724; called by muse, mutect2, varscan2
- NUP214 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs150328396; called by muse, mutect2, varscan2
- OPRPN | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.041); catalogued as COSV68192627; called by muse, mutect2, varscan2
- OR52R1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866610632, COSV61887615; called by muse, mutect2, varscan2
- PPP3CA | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59921756; called by muse, mutect2, varscan2
- PRAMEF6 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.147); catalogued as rs3855731; called by muse, mutect2, varscan2
- RABGAP1L | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1048001095; called by muse, mutect2, varscan2
- RPS6KA1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV65176550; called by muse, mutect2, varscan2
- TENM1 | c.5855G>A p.R1952Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs201279168, COSV64429887; called by muse, mutect2, varscan2
- TRAPPC11 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752448315, COSV58217923; called by muse, mutect2, varscan2
- ZNF611 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.035); catalogued as COSV60542008; called by muse, mutect2, varscan2
- ANKRD62 | c.2627C>A p.A876D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CFTR | c.3720G>A p.V1240= | Splice Region (SNP) | VAF 50/279 reads (18%) | called by muse, mutect2, varscan2
- CFTR | c.3721G>A p.G1241S | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4E | c.24A>C p.E8D | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLTCL1 | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DPYSL2 | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GEN1 | c.355del p.H119Ifs*6 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel
- HDAC7 | c.2125C>A p.H709N (on ENST00000427332; = p.H748N on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRIQ3 | c.776A>C p.Y259S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MAML3 | c.1033G>C p.A345P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MTX1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC5B | c.12524G>T p.R4175L | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- P2RY4 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PARD3 | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA12 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 137/415 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLXNA1 | c.1936dup p.E646Gfs*47 | Frame Shift Ins (INS) | VAF 64/241 reads (27%) | called by mutect2, pindel, varscan2
- PRSS36 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PTPRQ | c.2014_2015del p.K672Efs*22 (on ENST00000616559; = p.K630Efs*22 on NM_001145026.2) | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- TCF12 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TOP3A | c.2079C>A p.D693E | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TRIM32 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TUT4 | c.970_972del p.K324del | In Frame Del (DEL) | VAF 41/153 reads (27%) | called by mutect2, pindel, varscan2
- VPS13A | c.4974A>G p.I1658M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZFYVE26 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACTL7A | c.894G>A p.T298= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as rs778200118; called by muse, mutect2, varscan2
- ANKRD62 | c.2628T>A p.A876= | Silent (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.1731C>T p.A577= | Silent (SNP) | VAF 61/198 reads (31%) | catalogued as rs989984704; called by muse, mutect2, varscan2
- ARHGEF17 | c.4197C>T p.F1399= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1222904447; called by muse, mutect2, varscan2
- C7orf31 | c.744C>T p.F248= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs139391560; called by muse, mutect2
- CD1A | c.615G>A p.E205= | Silent (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- DACH1 | c.1737G>T p.P579= (on ENST00000619232 / NM_001366712.1; = p.P325= on NM_004392.6) | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as rs370706409, COSV57512761; called by muse, mutect2, varscan2
- EPHB3 | c.132C>T p.D44= | Silent (SNP) | VAF 43/169 reads (25%) | called by muse, mutect2, varscan2
- GGT7 | c.330C>T p.I110= | Silent (SNP) | VAF 74/278 reads (27%) | catalogued as rs758677980, COSV60540192; called by muse, mutect2, varscan2
- L1CAM | c.2577G>A p.R859= | Silent (SNP) | VAF 94/187 reads (50%) | called by mutect2, varscan2
- MAP2 | c.3003C>A p.A1001= | Silent (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- OR4D11 | c.261A>C p.S87= | Silent (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- OR4K2 | c.732C>T p.F244= | Silent (SNP) | VAF 75/191 reads (39%) | catalogued as rs141738617, COSV53849732; called by muse, mutect2, varscan2
- PARD3 | c.2712G>A p.G904= | Silent (SNP) | VAF 80/270 reads (30%) | catalogued as rs978229324; called by muse, mutect2, varscan2
- PFKFB2 | c.570C>T p.F190= | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- PFKFB2 | c.571C>T p.L191= | Silent (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- PRAMEF6 | c.1251G>A p.R417= | Silent (SNP) | VAF 47/326 reads (14%) | catalogued as rs1352089969; called by muse, mutect2, varscan2
- PRSS36 | c.414C>T p.A138= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as rs764054851; called by muse, mutect2, varscan2
- PTPDC1 | c.471C>T p.F157= (on ENST00000375360 / NM_177995.3; = p.F209= on NM_152422.4) | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs751926700, COSV56621157; called by muse, mutect2, varscan2
- RABGAP1L | c.432C>T p.S144= | Silent (SNP) | VAF 61/212 reads (29%) | catalogued as rs1438172109, COSV99267477; called by muse, mutect2, varscan2
- SOWAHA | c.1077C>T p.G359= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- ZNF596 | c.763C>T p.L255= | Silent (SNP) | VAF 56/154 reads (36%) | called by muse, mutect2, varscan2
- CABP1 | c.655-3865C>T | Intron (SNP) | VAF 26/68 reads (38%) | catalogued as COSV99974493; called by muse, mutect2, varscan2
- GLP2R | c.*305G>A | 3'UTR (SNP) | VAF 31/146 reads (21%) | called by muse, mutect2, varscan2
- NPAS3 | c.558+18030C>A | Intron (SNP) | VAF 33/135 reads (24%) | called by muse, varscan2
- PPM1F | c.355+1328G>T | Intron (SNP) | VAF 70/160 reads (44%) | catalogued as rs77566057; called by muse, mutect2, varscan2
- SSX9P | n.434G>T | RNA (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.-1-9C>T | Intron (SNP) | VAF 92/336 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.34264+2925C>T | Intron (SNP) | VAF 50/164 reads (30%) | catalogued as rs1560217891; called by muse, mutect2, varscan2
- ZNF890P | n.541C>T | RNA (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ZNF890P | n.540C>T | RNA (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
